Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7891, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7891-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Inquiry Numbers:

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Specimen Description

A. Node of importance

B. Pancreatic margin

C. Whipple specimen

Clinical Information

MRI showed a lump on pancreas.

Diagnosis

A. Lymph Node (Node of Importance), Excision:

- 1 lymph node, negative for malignancy (0/1).

B. Pancreas (Margin), Biopsy:

- Atrophic pancreas, negative for malignancy.

C. Small Bowel, Pancreas, Bile Duct, Whipple excision:

- Pancreatic well-differentiated ductal adenocarcinoma (see Synoptic Report).
- Pancreatic intraepithelial neoplasia, high-grade (PanIN III/III).
- Lymphovascular space invasion identified.
- Extensive perineural invasion identified.
- Metastatic adenocarcinoma in 7/11 lymph nodes.

[page 2 of 4]
- Tumor present < 0.1 cm from bile duct margin, distal pancreatic and uncinata margin.
- Ampullary epithelium with reactive atypia and submucosal fibro-inflammatory response, secondary to stent.

Reported by: [REDACTED]

Synoptic Report

C: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G1: Well differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades peripancreatic soft tissues

Tumor invades retroperitoneal soft tissue

MARGINS:

Distance of invasive carcinoma from closest margin: 1 mm

Specified margin: uncinata, distal pancreas, bile duct margin

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 11

Number involved: 7

ADDITIONAL PATHOLOGIC FINDINGS:

[page 3 of 4]
Surgical Pathology Report

Inquiry Numbers:

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Pancreatic Intraepithelial neoplasia (highest grade: PanIN 3)

C: Pancreas (Exocrine), Macroscopic

SPECIMEN:

Head of pancreas

Duodenum

Common bile duct

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension: 2.7 cm

Gross Description

Received are specimens A to C. All requisitions and specimen containers are labelled with the patient's name. The cassettes and AP identifiers are labelled with the Surgical Number

The specimens were received fresh, submitted for tumor bank, and photographs were taken.

A. The specimen consists of a single fragment of tan and fatty tissue measuring 1.7 x 1.3 x 0.5 cm. The entire specimen is sectioned and submitted in toto in cassette A1.

B. The specimen consists of one piece of tissue measuring 0.8 x 0.7 x 0.1 cm. Submitted in toto for QS.

C. The specimen consists of distal stomach (2.0 cm in length, 5.1 cm in circumference), small bowel (19.0 cm in length, 7.0 cm in circumference), pancreas head (5.5 x 4.5 x 4.0 cm), and a small length of bile duct (0.5 cm in length x 0.5 x 0.5 cm). Surgical margins are painted as follows: Pancreas uncinata margin in yellow, posterior margin in black, and the pancreas neck is painted in blue. Distal stomach demonstrates no evidence of ulceration. The wall is pliable and the serosa is unremarkable. The length of duodenum demonstrates no nodularities. The serosal surface is smooth and unremarkable with no nodularities. The wall of the small bowel is pliable and uniform. The mucosal surface demonstrates a small nodularity and raised mucosal surface over the areas of the ampulla located 2.0 cm from the proximal margin. At 1.0 cm proximal the ampulla, is another firm nodularity which does not appear to be probed patent. The nodularity of ampulla of Vater measures approximately 1.0 x 1.0 x 1.5 cm.

Upon sectioning of the pancreas, there is a firm nodular ill-defined white mass located around the common bile duct as it enters the pancreas. This mass measures approximately 2.3 x 2.3 x 1.7 cm. The mass does not appear to invade the

[page 4 of 4]
Surgical Pathology Report

Inquiry Numbers:

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

small bowel grossly. Pancreatic sections are submitted in successive levels from the proximal pancreatic neck margin towards the uncinate margin in numbered levels cut transversely. Mass comes to within 0.2 cm of the uncinate margin and grossly appears to approach the posterior margin. Blocks are submitted as follows:

- C1. bile duct margin
- C2. pancreas level 1, representative sections of small bowel
- C3-4. pancreas level 2
- C5-6. pancreas level 3
- C7-9. pancreas level 4
- C10-12. pancreas level 5
- C13-14. ampulla
- C15-16. pancreas level 6
- C17-18. pancreas level 7
- C19. bowel specimen margin
- C20. four possible lymph nodes, two bivalved

Frozen Section Diagnosis

B. Pancreatic Margin:

Negative for malignancy, chronic pancreatitis. Interdepartmental consult with Dr

Reported by:

Pathologist Comment

Frozen section diagnosis has been confirmed.

Source: NCI Genomic Data Commons file 01bc3497-8ba7-4766-af36-bdf261852289 (TCGA-IB-7891.1C80A890-16CD-445F-92AE-811DA23D6DFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).